Surgical pathology report (de-identified scan), TCGA case TCGA-CS-6669, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-6669-01A (Primary Tumor).

[page 1 of 6]
ADDED

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right temporal tumor: OLIGODENDROGLIOMA, GRADE ii OF iv (who SCALE), SEE MICROSCOPIC DESCRIPTION
2. Right temporal lobe tumor: OLIGODENDROGLIOMA, GRADE ii OF iv (who SCALE), SEE MICROSCOPIC DESCRIPTION
3. Right temporal lesion: Pending complete submission of remaining tissue.

Comment:

The ki-67 proliferation index is 4.5%. Several studies have indicated that oligodendrogliomas with proliferation indices of greater than 5% are associated with a significantly decreased five-year survival rate compared to those with proliferation indices of less than 5%. The different survival rates are, respectively, 83% versus 24% (1). FISH for the 1p/19q deletion has been ordered and when completed, a separate report will be issued.

This diagnostic report has been personally interpreted by the signatory of record.

Ki67
Percent : 4.5
3+ % : 3.1
2+ % : 0.65
1+ % : 0.7
0 % : 95.47
Cells counted : 128,037

[page 2 of 6]
This test was performed by in conjunction with the assisted image analysis.

Addendum

Specimen #3 contains small quantities of infiltrating oligodendroglioma, grade II.

All tissue for specimen #3 has been submitted.

Microscopic Description:

1. Right temporal tumor:

History of Previous Tumor/Familial Syndrome:	None known
Specimen Type/Procedure:	Resection
Specimen Handling:	Squash / smear / touch preparation
	Frozen section
Specimen Size:	Cannot be determined: Multiple separate specimens
Laterality:	Right
Tumor Site:	Brain/cerebrum-Temporal
Histologic Type and Grade:	Oligodendroglioma (WHO grade II)
Histologic Grade:	WHO Grade II
Margins:	Cannot be assessed
Ancillary Studies:	Immunohistochemistry: Ki67

Frozen Section Diagnosis:

1. Right temporal tumor: Glial neoplasm. No obvious anaplasia in this material.-

Clinical History and Diagnosis:
brain mass

[page 3 of 6]
Source of Specimen:

- 1: Right temporal tumor
- 2: Right temporal lobe tumor
- 3: Right temporal lesion

Gross Description:

1. Right temporal tumor: Received fresh for frozen section analysis in a specimen container labeled with the patient's name and "#1 right temporal tumor consistent with low-grade glioma" is a single fragment of tan-pink soft tissue measuring 1.5 x 1.0 x 0.5 cm. Touch preps are prepared. Approximately 80% of the specimen is submitted for frozen section analysis. The specimen is entirely submitted in 2 cassettes as follows:

- A frozen section control
- B. remainder of the specimen

2. Right temporal lobe tumor: Received fresh in a specimen container labeled with the patient's name and "#2 right temporal lobe tumor consistent with glioma" are multiple fragments of tan-pink soft tissue measuring 1.2 x 0.5 x 0.4 cm in aggregate. The specimen is entirely submitted in 1 cassette.

3. Right temporal lesion: Received in formalin in the specimen are labeled with the patient's name and "#3 right temporal lesion" single fragment of tan-pink soft tissue measuring 5.3 x 2.1 0.4 cm. The specimen is serially sectioned to reveal tan-pink and tan-white cut surfaces. No discrete lesions are identified grossly. The entire specimen has been submitted.

Histology Laboratory

Part 1: Right temporal tumor
1p - FISH
KI 67 (Aperio)
MOLECULAR H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of [REDACTED] et.al. [REDACTED]

2. Pathway Her-2/neu (4B5) (Rabbit monoclonal) - Formalin-fixed, paraffin embedded tissue. [REDACTED]

[page 4 of 6]
3. EGFR (3C6) (Mouse Monoclonal) Formalin-fixed, paraffin embedded tissue. [REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[page 5 of 6]
[REDACTED]

[REDACTED]

MEDICAL GENETICS REPORT

EVALUATION:

ASSAY PERFORMED: del(1p)del(19q) BY FLUORESCENCE IN-SITU HYBRIDIZATION (FISH)

RESULT: Positive for the deletion of 1p
Positive for the deletion of 19q

NOMENCLATURE:nuc ish 1p36(P73 x 1~3),1q24(ANGPTL1 x 1~3)[200]/19p13(ZNF44 x 1~5),19q13(GLTSCR x 1~3)[200]

1p36/1q24

Number of Nuclei scored: 200

Ratio of 1p/1q: 0.60

% cells with del 1p: 71%

19q13/19p13

Number of Nuclei scored: 200

Ratio of 19q/19p: 0.56

% cells with del 19q: 73%

INTERPRETATION: The results are less than the normal range and suggest deletions of 1p and 19q in this Oligodendroglioma [REDACTED] del (1p) and del(19q) has been observed in glioma specimens, especially oligodendrogliomas. Clinical and pathologic correlation is recommended.

Comment:

[REDACTED] [REDACTED]

(Cytogeneticist)

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

[page 6 of 6]
10/1/2010

Normal range: The normal ratio is approximately 1. Any ratio > 0.80 is considered normal.

COMMENT: This test was developed and its performance characteristics determined by the Molecular Pathology Laboratory at [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration. This test is not to be used as a diagnostic procedure without confirmation of the diagnosis by another medically established product or procedure.

██████████

Source: NCI Genomic Data Commons file 26d2ece0-e8b0-4300-81c2-afbbb660f16a (TCGA-CS-6669.4D8ABB1C-F9A3-4E9B-8140-1B8F7CC9BA5B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).